Somatic mutation profile of tumor specimen ALCH-B05K-TTP1-A (aliquot ALCH-B05K-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.0 years (15,691 days).
Specimen ALCH-B05K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c695372-c5cf-4970-9b01-4719c096fa10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05K-NB1-A (Blood Derived Normal), aliquot ALCH-B05K-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0beeff4a-1b6f-4112-8664-d28a3cf0798e

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, RNA 3, Frame Shift Del 3, Intron 2, Splice Region 2, 5'UTR 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 180/719 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CATSPERD | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58464946; called by muse, mutect2
- CDH22 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs918808597, COSV64836484; called by muse, mutect2, varscan2
- CPSF7 | c.484C>T p.R162W (on ENST00000394888 / NM_001136040.4; = p.R205W on NM_024811.4) | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61210055; called by muse, mutect2
- FBN3 | c.5011C>T p.R1671W | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs548011190, COSV54464493; called by muse, mutect2, varscan2
- NBAS | c.5269G>C p.E1757Q | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV55711890; called by muse, mutect2
- PCDHB12 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); catalogued as rs1163263707, COSV53393859; called by muse, mutect2
- PKDREJ | c.1768A>C p.K590Q | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs766536222; called by muse, mutect2
- PRSS58 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 24/577 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101616119; called by muse, mutect2
- PTPRT | c.2772C>T p.Y924= | Splice Region (SNP) | VAF 24/60 reads (40%) | catalogued as rs758202722, COSV100626023; called by muse, mutect2, varscan2
- RAPGEF5 | c.406G>A p.E136K (on ENST00000401957 / NM_001367602.2; = p.E439K on NM_012294.5) | Missense Mutation (SNP) | VAF 65/626 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59784724; called by muse, mutect2, varscan2
- TGFBR1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as rs1554698880, COSV66625965; ClinVar: uncertain significance; called by muse, mutect2
- TNN | c.1546G>C p.G516R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53427261; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 104/342 reads (30%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- ZNF582 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100018824; called by muse, mutect2, varscan2
- ANKRD37 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 114/440 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN2L | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CCT2 | c.1217C>G p.T406R | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); called by muse, mutect2
- CD163L1 | c.1175C>A p.T392K | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CENPF | c.6122A>T p.E2041V | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CEP76 | c.1943G>T p.W648L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GABRA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/505 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, mutect2
- GSS | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MAP4K1 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.086); called by muse, mutect2
- MLLT1 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MMP2 | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2
- MMS22L | c.1418A>C p.E473A | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.39885T>A p.T13295= | Splice Region (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- MYH6 | c.4396C>T p.Q1466* | Nonsense Mutation (SNP) | VAF 24/371 reads (6%) | called by muse, mutect2
- OR52D1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- PAPPA2 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB16 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.547); called by muse, mutect2
- SLC34A2 | c.1747del p.L583Cfs*18 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by pindel, varscan2
- SLC9C1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SYNCRIP | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.163); called by muse, mutect2
- TLR8 | c.2292A>C p.L764F (on ENST00000218032 / NM_138636.5; = p.L782F on NM_016610.4) | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ2 | c.1269del p.L424* | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- TTC21B | c.1986C>G p.D662E | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.179); called by muse, mutect2
- UBAP2L | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZMIZ2 | c.572T>C p.F191S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ZUP1 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- CENPC | c.1986A>T p.T662= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- FAM135B | c.1380T>G p.L460= | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- HEATR1 | c.3672G>A p.Q1224= | Silent (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- IGF2BP1 | c.1332C>T p.P444= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs188731587, COSV51732745; called by muse, mutect2, varscan2
- PPP1R21 | c.564G>A p.K188= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as COSV99682368; called by muse, mutect2
- PPT2 | c.132G>A p.G44= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs770290541; called by muse, mutect2
- SPEG | c.7809G>T p.L2603= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- SPTBN5 | c.7452C>T p.V2484= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- TPSG1 | c.693C>T p.N231= | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as rs760381250, COSV99327107; called by muse, mutect2, varscan2
- WNK2 | c.6729G>A p.V2243= (on ENST00000297954 / NM_001282394.1; = p.V2206= on NM_006648.3) | Silent (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2, varscan2
- ZBTB10 | c.324T>A p.G108= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3524A>G | RNA (SNP) | VAF 16/293 reads (5%) | called by muse, mutect2
- LINC02035 | n.169T>G | RNA (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- LRP11 | c.1348+42C>G | Intron (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- MACF1 | c.16491+544T>G | Intron (SNP) | VAF 58/662 reads (9%) | called by muse, mutect2
- OR2L1P | n.947C>G | RNA (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- TEX35 | c.-8C>T | 5'UTR (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
